Somatic mutation profile of tumor specimen TCGA-06-2563-01A (aliquot TCGA-06-2563-01A-01W-0837-08) from TCGA case TCGA-06-2563, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.9 years (26,643 days).
Specimen TCGA-06-2563-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a000a829-d866-446d-bb53-e4094ecac7a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2563-10A (Blood Derived Normal), aliquot TCGA-06-2563-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b7c651c-4c61-4e55-a2ec-9750b2b8b3ad

The open-access MAF lists 92 somatic variants for this specimen: 70 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 20, Nonsense Mutation 5, Frame Shift Ins 3, Splice Site 2, Frame Shift Del 2, Splice Region 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 3046/3363 reads (91%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV51767495, COSV51850592; called by muse, mutect2, varscan2
- KCNH2 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs370637245, CM139886; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- LDLRAP1 | c.603dup p.S202Lfs*19 | Frame Shift Ins (INS) | VAF 8/74 reads (11%) | catalogued as rs781585299; ClinVar: pathogenic; called by pindel, varscan2
- TP53 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 51/151 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131691013, CM120849, CM134998, COSV52681833, COSV52696302, COSV52721346, COSV53165479; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACA | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 88/201 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs781293486; called by muse, mutect2, varscan2
- AFF2 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 255/538 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782378680, COSV53977676; called by muse, mutect2, varscan2
- AL121899.2 | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 456/1038 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs778533516, COSV101198680, COSV67349775; called by muse, mutect2, varscan2
- ANKRD35 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 256/1114 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs782131391, COSV62909596; called by muse, mutect2, varscan2
- ATP8B4 | c.90T>A p.D30E | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as COSV52709738, COSV52713583; called by muse, mutect2, varscan2
- BCLAF3 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 88/404 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61413189; called by muse, mutect2, varscan2
- BRD9 | c.1599C>G p.D533E | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as COSV60244755; called by muse, mutect2, varscan2
- C1orf116 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.98); PolyPhen benign (0.019); catalogued as rs757897878, COSV63943767; called by muse, mutect2, varscan2
- CCDC146 | c.2468T>C p.L823P | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV53544215; called by muse, mutect2, varscan2
- CHSY3 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.374); catalogued as COSV59271786; called by muse, mutect2, varscan2
- CLEC1A | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 355/712 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.208); catalogued as rs147882348, COSV100191187, COSV59531017; called by muse, mutect2, varscan2
- CLPP | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55536166; called by muse, mutect2, varscan2
- CPA4 | c.68+1G>A p.X23_splice | Splice Site (SNP) | VAF 48/281 reads (17%) | catalogued as rs1562926594, COSV55979179; called by muse, varscan2
- CYP7B1 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 151/350 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394828774, COSV59582859; called by muse, mutect2, varscan2
- DNAH3 | c.5696G>A p.R1899H | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1410835335, COSV54504976; called by muse, mutect2, varscan2
- ERICH3 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV58599822; called by muse, mutect2, varscan2
- FBXO38 | c.638T>G p.L213R | Missense Mutation (SNP) | VAF 92/164 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57025959; called by muse, mutect2, varscan2
- GATA3 | c.708dup p.S237Qfs*66 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | catalogued as rs771019738, COSV60521878; called by mutect2, varscan2
- GRIP2 | c.1574G>A p.R525Q (on ENST00000619221; = p.R428Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as rs1442488155, COSV56123353; called by muse, mutect2, varscan2
- HECW1 | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs953667034, COSV101223049, COSV67822507, COSV67839582; called by muse, mutect2, varscan2
- IDE | c.1065G>C p.W355C | Missense Mutation (SNP) | VAF 71/343 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56421624; called by muse, mutect2, varscan2
- KEL | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 146/307 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV62333430; called by muse, mutect2, varscan2
- KRT33A | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 312/500 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as rs746529701, COSV50365651; called by muse, mutect2
- LPAR4 | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 145/294 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70912243; called by muse, mutect2, varscan2
- LRP2 | c.4927C>T p.R1643W | Missense Mutation (SNP) | VAF 106/317 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); catalogued as rs140789320; called by muse, mutect2, varscan2
- LY75 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754070568, COSV55102226, COSV99716270; called by muse, mutect2, varscan2
- LZTS1 | c.69C>A p.Y23* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | catalogued as rs929104136; called by muse, mutect2
- MAPKBP1 | c.2228G>A p.R743H (on ENST00000456763 / NM_001128608.2; = p.R737H on NM_014994.3) | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs534654016, COSV52958394; called by muse, mutect2, varscan2
- NCDN | c.1385+1G>A p.X462_splice | Splice Site (SNP) | VAF 20/52 reads (38%) | catalogued as COSV61934714; called by muse, mutect2, varscan2
- OPHN1 | c.959A>G p.Y320C | Missense Mutation (SNP) | VAF 147/332 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV62780435; called by muse, mutect2, varscan2
- OR11H6 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs946398048, COSV59643724; called by muse, mutect2, varscan2
- OR2C3 | c.619T>C p.F207L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV63574406; called by muse, mutect2, varscan2
- OR51M1 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 512/1386 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100150094, COSV60785117; called by muse, mutect2, varscan2
- PCLO | c.15422C>T p.T5141M | Missense Mutation (SNP) | VAF 423/1217 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV61626766; called by muse, mutect2, varscan2
- PCLO | c.9254C>A p.S3085Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100437881; called by muse, mutect2, varscan2
- PNPLA1 | c.377G>A p.R126H (on ENST00000394571 / NM_001374623.1; = p.R31H on NM_173676.2) | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768351117, COSV57232602; called by muse, mutect2, varscan2
- POF1B | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.223); catalogued as COSV53130567; called by muse, mutect2, varscan2
- PRICKLE4 | c.580A>G p.S194G (on ENST00000359201; = p.S234G on NM_013397.6) | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59253639; called by muse, mutect2, varscan2
- PSG7 | c.611T>A p.L204Q | Missense Mutation (SNP) | VAF 697/1960 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV68446007; called by muse, mutect2, varscan2
- PTX4 | c.1243G>A p.D415N (on ENST00000447419 / NM_001328608.2; = p.D410N on NM_001013658.1) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs149572258, COSV53514427; called by muse, mutect2, varscan2
- RIMS2 | c.1655C>T p.T552M (on ENST00000666250 / NM_001348490.2; = p.T360M on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 186/342 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs774568019, COSV51655052; called by muse, mutect2, varscan2
- RPL10L | c.99del p.F34Lfs*44 | Frame Shift Del (DEL) | VAF 65/216 reads (30%) | catalogued as COSV53558602, COSV53558723; called by mutect2, pindel, varscan2
- SACS | c.5608G>A p.V1870M | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.156); catalogued as rs752750902, COSV101207418; called by muse, mutect2, varscan2
- SCNN1A | c.1233C>A p.Y411* | Nonsense Mutation (SNP) | VAF 80/186 reads (43%) | catalogued as COSV57434154; called by muse, mutect2, varscan2
- SIRT3 | c.516T>G p.D172E | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV61500379; called by muse, mutect2, varscan2
- SLC26A3 | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.919); catalogued as COSV60638853; called by muse, mutect2, varscan2
- SLCO6A1 | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV65805962, COSV65811106; called by muse, mutect2, varscan2
- SPRR1A | c.68A>T p.Q23L | Missense Mutation (SNP) | VAF 273/776 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV61080931; called by muse, mutect2, varscan2
- SRRM2 | c.6685G>C p.A2229P | Missense Mutation (SNP) | VAF 79/285 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51939909; called by muse, mutect2, varscan2
- TIAM2 | c.4041A>C p.V1347= (on ENST00000529824; = p.V1318= on NM_012454.3) | Splice Region (SNP) | VAF 54/180 reads (30%) | catalogued as COSV51637847; called by muse, mutect2, varscan2
- TJP1 | c.3205C>T p.Q1069* | Nonsense Mutation (SNP) | VAF 18/470 reads (4%) | catalogued as COSV100632997; called by muse, mutect2
- TLR9 | c.2965C>A p.R989S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs747414072, COSV62345599, COSV62346408; called by muse, varscan2
- TMEM132D | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs751041490, COSV70594645; called by muse, mutect2, varscan2
- TNIP3 | c.456G>C p.K152N | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs1459060271, COSV50245890; called by muse, mutect2, varscan2
- TRPM2 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs762836395, COSV55966247; called by muse, mutect2, varscan2
- VAV1 | c.71C>A p.T24N | Missense Mutation (SNP) | VAF 82/317 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV58379041; called by muse, mutect2, varscan2
- WSCD2 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs567916978, COSV54578386; called by muse, mutect2, varscan2
- ZNF280C | c.509_510del p.S170Lfs*10 | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | catalogued as COSV63968525; called by mutect2, pindel, varscan2
- ZPBP | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 79/298 reads (27%) | catalogued as rs201826735, COSV50422619; called by muse, mutect2, varscan2
- CCDC25 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2
- CNOT1 | c.20C>A p.S7* | Nonsense Mutation (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- EPHB4 | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2
- EVX2 | c.801C>A p.H267Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by mutect2, varscan2
- HMX2 | c.249dup p.I84Hfs*34 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by pindel, varscan2
- LGR4 | c.2761G>A p.D921N | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- SNPH | c.23G>T p.S8I | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- CSMD3 | c.1122T>A p.P374= | Silent (SNP) | VAF 54/204 reads (26%) | catalogued as COSV52108376; called by muse, mutect2, varscan2
- EPN3 | c.471G>A p.E157= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs750829727, COSV52141936; called by muse, mutect2, varscan2
- FOXO1 | c.1698G>A p.L566= | Silent (SNP) | VAF 31/254 reads (12%) | called by muse, mutect2, varscan2
- GRIA3 | c.933C>T p.H311= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs148850386, COSV52048528, COSV52049984; ClinVar: likely benign; called by muse, mutect2, varscan2
- GUCY2F | c.1785C>T p.F595= | Silent (SNP) | VAF 530/1413 reads (38%) | catalogued as rs1299126087, COSV54298769; called by muse, mutect2, varscan2
- KRT18 | c.264C>T p.N88= | Silent (SNP) | VAF 49/113 reads (43%) | catalogued as rs1353724071, COSV66315875; called by muse, mutect2, varscan2
- LAMP2 | c.1116C>T p.D372= | Silent (SNP) | VAF 155/595 reads (26%) | catalogued as rs749338632, COSV52351527; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEC1 | c.2454C>T p.P818= | Silent (SNP) | VAF 180/769 reads (23%) | catalogued as COSV53568354; called by muse, mutect2, varscan2
- MAPKBP1 | c.1020G>A p.A340= (on ENST00000456763 / NM_001128608.2; = p.A334= on NM_014994.3) | Silent (SNP) | VAF 217/581 reads (37%) | catalogued as rs762867127, COSV52958379; called by muse, mutect2, varscan2
- MYBPC2 | c.813C>A p.G271= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV63098185; called by muse, mutect2, varscan2
- PHOSPHO1 | c.780G>A p.L260= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV56800383; called by muse, mutect2
- POLR2A | c.1902G>A p.E634= | Silent (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- PTPRR | c.1126C>A p.R376= | Silent (SNP) | VAF 117/325 reads (36%) | catalogued as COSV51725254; called by muse, mutect2, varscan2
- SLIT3 | c.1147C>T p.L383= | Silent (SNP) | VAF 76/203 reads (37%) | catalogued as COSV60593810; called by muse, mutect2, varscan2
- SMARCA1 | c.123C>T p.A41= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV64410948; called by muse, mutect2, varscan2
- SYCP2L | c.2136C>T p.F712= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- TMEM255B | c.354C>G p.P118= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV100943130, COSV64704526; called by muse, mutect2, varscan2
- TNNT1 | c.286C>T p.L96= | Silent (SNP) | VAF 39/185 reads (21%) | catalogued as rs1431234828; called by muse, mutect2, varscan2
- VWCE | c.1116G>A p.R372= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV57111056; called by muse, mutect2, varscan2
- ZNF662 | c.444A>G p.E148= | Silent (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- HHIPL1 | c.1730+577G>A | Intron (SNP) | VAF 41/79 reads (52%) | catalogued as COSV58089231; called by muse, mutect2, varscan2
- MIR508 | n.37G>T | RNA (SNP) | VAF 82/138 reads (59%) | called by muse, mutect2, varscan2
